Surgical pathology report (de-identified scan), TCGA case TCGA-18-4083, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Princess Margaret Hospital (Canada), specimen TCGA-18-4083-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Lymph-Node: ST10L TB Angle
2. Lymph-Node: ST11 Interlobar
3. Lymph-Node: ST11 Interlobar
4. LUNGS: LLL with resection margins

DIAGNOSIS

1-3. Lymph nodes, biopsies (ST10L left TB angle, ST11 interlobar, ST11 interlobar):

- Lymph nodes, negative for carcinoma (x3)

4. Lung, resection (left lower lobe):

a) Invasive poorly differentiated squamous cell carcinoma, with:

- i) Greatest dimension = 4.0 cm
- ii) Pleural invasion not identified
- iii) Bronchial resection margin negative for tumor
- iv) Venous invasion present

v) One lobar lymph node of nine lymph nodes in total, positive for metastatic adenocarcinoma (1/9)

b) Lung with post-obstructive edema, inflammation, and organizing pneumonia

SYNOPTIC DATA

Specimen Type:	Lobectomy
Laterality:	Left
Tumor Site:	LLL
Tumor Size:	Greatest dimension: 4.0 cm
Histologic Type:	Squamous cell carcinoma
Histologic Grade:	G3: Poorly differentiated
Pathologic Staging (pTNM):	pT2: Tumor with any of the following
Features of size or extent:	greater than 3 cm in greatest dimension;
	involves main bronchus, 2 cm or more distal to the carina; invades the

[page 2 of 4]
visceral pleura; associated with atelectasis or obstructive pneumonitis that extends to the hilar region but does not involve the entire lung

pN1: Metastasis in ipsilateral peribronchial and/or ipsilateral hilar lymph nodes, including intrapulmonary nodes involved by direct extension of the primary tumor
Lymph node stations involved: 12L (Left lobar)

PMX: Cannot be assessed
Margins: Margins uninvolved by invasive carcinoma

Direct Extension of Tumor: None identified

Venous (Large Vessel) Invasion (V): Present

Arterial (Large Vessel) Invasion: Absent

Additional Pathologic Findings: Other: Post-obstructive changes

COMMENT

Sections show a poorly differentiated central tumor with focal evidence of squamous differentiation. The tumor focally invades small venous vessels. By immunohistochemistry, the tumor stains positive for high molecular weight keratin, CK5/6, and p63, focally positive for CD56, and negative for CK7, CK20, TTF-1, chromogranin, and synaptophysin, consistent with squamous cell carcinoma. Selected slides from the patient's previous resection were reviewed for comparison, and show a squamous cell carcinoma with extensive keratinization that appears morphologically different from the present tumor. While a dedifferentiated metastasis cannot be definitively excluded, the present lung tumor is therefore favored to represent a second primary squamous cell carcinoma, stage pT2N1.

GROSS DESCRIPTION

1. The specimen container labeled with the patient's name and as "lymph node: ST10L TB angle". The specimen is received in 10% buffered formalin and consists of two irregular pieces of brown-tan, focally hemorrhagic,

[page 3 of 4]
soft to firm tissue ranging in size from 0.8 x 0.3 x 0.3 cm up to 2.5 x 0.6 x 0.4 cm. Cross sectioning reveals three probable lymph nodes, the largest measuring 0.7 cm in diameter. The cut surface of the lymph nodes is homogeneously tan, focally hemorrhagic and firm. The specimen is submitted in toto as follows:

1A to 1C - one bisected probable lymph node per block

2. The specimen container labeled with the patient's name and as "lymph node: ST11 interlobar". The specimen is received in 10% buffered formalin and consists of two pieces of black to tan, firm tissue; ranging in size from 0.4 x 0.3 x 0.2 cm up to 0.7 x 0.3 x 0.3 cm.

2A - specimen submitted in toto

3. The specimen container labeled with the patient's name and as "lymph node: ST11 interlobar". The specimen is received in 10% buffered formalin and consists of an irregular, brown-tan, firm piece of tissue measuring 1.7 x 0.6 x 0.5 cm. On sectioning, the cut surface is homogeneously tan and focally hemorrhagic.

3A - specimen bisected and submitted in toto.

4. The specimen container is labeled with the patient's name and as "lungs: LLL with resection margins". The specimen is received fresh and subsequently placed into 10% buffered formalin. It contains a left lower lobe of lung. The overall measurement of the specimen is 17.7 x 11.5 x 6 cm. The pleural surface appears purple-tan and smooth. One dark purple, congested area is seen within the pleura. Cross sections of this area reveal one large, well circumscribed tumour measuring 4 x 4 x 3.7 cm. Cross sections of the tumour appear homogeneously white-tan, friable and necrotic in the centre; tan and firm towards the periphery. The tumour is located 0.3 cm from the closest pleural surface and approximately 0.8 cm from the bronchial resection line. However, the tumour is seen invading one of the adjacent bronchi, completely obliterating the bronchial wall and invading into the lumen. The tumour is located approximately 0.2 cm from the resection margin of this bronchus. Further sectioning of the lobe shows a homogeneously brown-tan parenchyma with dilated bronchi, which appear partially calcified. The lumina of the bronchi show white/tan gelatinous material within them. Multiple probable lymph nodes are identified, the largest measuring 1.5 cm in diameter and is located at the hilar region of the specimen.

representative sections are submitted as follows:

4A - frozen section block resubmitted

[page 4 of 4]
[REDACTED]

[REDACTED]

[REDACTED]

4B to 4D - representative sections of tumour with adjacent pleura
4E to 4G - representative sections of tumour with pleura and hilum
(please note that block 4E contains a mirror image of block 4F)
4H to 4I - bisected representative section of tumour showing invasion
into adjacent bronchus
4J to 4K - representative sections of normal lung
4L - two probable lobar lymph nodes
4M - one bisected probable lobar lymph node
4N - four probable segmental lymph nodes
4O - one probable subsegmental lymph node
4P - one bisected probably subsegmental lymph node

(please note that three pieces of tumour and three pieces of normal lung
have been taken for tissue banking. Please also note that specimen number
four was examined at intraoperative consultation by frozen section on the
bronchial margin in one block.

[REDACTED]

QUICK SECTION

4A - Negative for malignancy

[REDACTED]

Source: NCI Genomic Data Commons file ea33cfd4-6d69-443e-b8c7-4bad907e7a4d (TCGA-18-4083.17A6525D-91D1-4CF5-B718-EA4C5E133A64.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).